Somatic mutation profile of cancer-model specimen HCM-BROD-0679-C43-85M (Adherent Cell Line, passage 8; aliquot HCM-BROD-0679-C43-85M-01D-A80U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0679-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 68.3 years (24,933 days).
Specimen HCM-BROD-0679-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 825b44a0-cdf0-49a8-a49f-f3a7abaae366.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0679-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0679-C43-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41b274de-9b58-442b-831f-9a3ae2274ff8

The open-access MAF lists 878 somatic variants for this specimen: 562 protein-altering or splice-affecting, 280 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 507, Silent 280, Nonsense Mutation 32, Intron 25, Splice Region 11, Splice Site 6, 3'UTR 3, 5'Flank 3, Frame Shift Del 3, RNA 3, 5'UTR 2, In Frame Del 1.

Variants (750 of 878; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL7A1 | c.6752G>A p.G2251E | Missense Mutation (SNP) | VAF 209/424 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs121912834, CM071647, CM980412; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 210/396 reads (53%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABL2 | c.2713C>T p.P905S (on ENST00000502732 / NM_007314.4; = p.P890S on NM_005158.5) | Missense Mutation (SNP) | VAF 541/817 reads (66%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); catalogued as COSV61011371; called by muse, mutect2, varscan2
- ACR | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 219/463 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.116); catalogued as rs368710046, COSV53360743; called by muse, mutect2, varscan2
- ADAMTSL4 | c.566G>A p.R189K | Missense Mutation (SNP) | VAF 217/661 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55009047, COSV99648185; called by muse, mutect2, varscan2
- ADCY5 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 125/259 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.05); catalogued as rs1311371744, COSV100567509; called by muse, mutect2, varscan2
- ADGRV1 | c.3232G>A p.E1078K | Missense Mutation (SNP) | VAF 154/323 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV67981171; called by muse, mutect2, varscan2
- ADH7 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 221/406 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146193104; called by muse, mutect2, varscan2
- AGBL3 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 134/261 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.358); catalogued as rs746965087, COSV51950655; called by muse, mutect2, varscan2
- AMELX | c.144G>A p.P48= | Splice Region (SNP) | VAF 179/179 reads (100%) | catalogued as rs149068672, COSV61629208; called by muse, mutect2, varscan2
- ANO5 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 80/185 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61084823; called by muse, mutect2
- ARHGAP17 | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 106/243 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as rs112438139, COSV99253854; called by muse, mutect2, varscan2
- ARHGEF38 | c.2110G>A p.G704S | Missense Mutation (SNP) | VAF 151/321 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as rs1367584311; called by muse, mutect2, varscan2
- ARID2 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 123/271 reads (45%) | catalogued as COSV57596634; called by muse, mutect2, varscan2
- ARID3B | c.1574C>T p.P525L (on ENST00000622429 / NM_001307939.1; = p.P524L on NM_006465.4) | Missense Mutation (SNP) | VAF 200/459 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs760067611; called by muse, mutect2, varscan2
- ARSH | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 192/192 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs755749697; called by muse, mutect2, varscan2
- ASXL1 | c.3865C>G p.R1289G | Missense Mutation (SNP) | VAF 201/428 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV60120509; called by muse, mutect2, varscan2
- ATF4 | c.731G>A p.R244K | Missense Mutation (SNP) | VAF 190/398 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57480537; called by muse, mutect2, varscan2
- ATRN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 101/205 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758948800, COSV53527986; called by muse, mutect2, varscan2
- ATXN1L | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 215/424 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101449083; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1221_1222insGTGACACCC p.P407_M408insVTP | In Frame Ins (INS) | VAF 123/380 reads (32%) | catalogued as rs1262419647; called by pindel, varscan2
- BAP1 | c.509T>G p.F170C | Missense Mutation (SNP) | VAF 218/451 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56239815; called by muse, mutect2, varscan2
- BCL11A | c.2110G>A p.G704S (on ENST00000335712 / NM_001365609.1; = p.G738S on NM_018014.4) | Missense Mutation (SNP) | VAF 213/476 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs1260030200; called by muse, mutect2, varscan2
- BCL11B | c.1057C>T p.P353S (on ENST00000357195 / NM_001282237.2; = p.P282S on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 266/552 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.145); catalogued as rs1211809833; called by muse, mutect2, varscan2
- BRINP3 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 323/510 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV66535691; called by muse, mutect2, varscan2
- C10orf62 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 239/240 reads (100%) | catalogued as rs1251830927; called by muse, mutect2, varscan2
- C14orf39 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs760333498, COSV58780487; called by muse, mutect2, varscan2
- CCDC144A | c.1709A>C p.H570P | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as rs1263117301; called by muse, mutect2, varscan2
- CCDC158 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 240/464 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs780553927; called by muse, mutect2, varscan2
- CCDC163 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 126/297 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.748); catalogued as COSV59151305; called by muse, mutect2, varscan2
- CCRL2 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 182/402 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV62193435; called by muse, mutect2, varscan2
- CD300LD | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 124/272 reads (46%) | catalogued as rs868469429, COSV60083582; called by muse, mutect2, varscan2
- CDC20B | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 172/358 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.484); catalogued as COSV57051927; called by muse, mutect2, varscan2
- CDHR3 | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 208/414 reads (50%) | catalogued as rs756269580; called by muse, mutect2, varscan2
- CELSR3 | c.3679G>A p.E1227K | Missense Mutation (SNP) | VAF 239/485 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs1217121769; called by muse, mutect2, varscan2
- CENPC | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 126/260 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs920266566; called by muse, mutect2, varscan2
- CHD5 | c.3110G>A p.R1037Q | Missense Mutation (SNP) | VAF 121/291 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs746052525, COSV52418365, COSV99313761; called by muse, mutect2, varscan2
- CLCA1 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 191/394 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs770005577, COSV52326014; called by muse, mutect2, varscan2
- CLDN18 | c.22G>C p.G8R | Missense Mutation (SNP) | VAF 141/327 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.165); catalogued as COSV59302390; called by muse, mutect2, varscan2
- CLEC18B | c.914G>A p.R305K | Missense Mutation (SNP) | VAF 58/505 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1407798531; called by muse, mutect2, varscan2
- CLMN | c.1856C>T p.S619L | Missense Mutation (SNP) | VAF 153/331 reads (46%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as rs370655092; called by muse, mutect2, varscan2
- CMYA5 | c.7306C>T p.P2436S | Missense Mutation (SNP) | VAF 113/238 reads (47%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.012); catalogued as COSV101484368, COSV71404171; called by muse, mutect2, varscan2
- COL14A1 | c.5077G>A p.G1693S | Missense Mutation (SNP) | VAF 100/220 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99918222; called by muse, mutect2, varscan2
- COL21A1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 99/211 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368730001; called by muse, mutect2, varscan2
- COL2A1 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 174/358 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs755370440; called by muse, varscan2
- COL2A1 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 174/362 reads (48%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.992); catalogued as COSV100476482; called by muse, varscan2
- COL4A2 | c.3035G>A p.G1012E | Missense Mutation (SNP) | VAF 160/327 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64626781; called by muse, mutect2, varscan2
- COL4A3 | c.4243G>A p.G1415R | Missense Mutation (SNP) | VAF 86/204 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM127661; called by muse, mutect2, varscan2
- COL5A2 | c.2672G>A p.G891D | Missense Mutation (SNP) | VAF 122/245 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66408901; called by muse, mutect2, varscan2
- CP | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 106/246 reads (43%) | SIFT tolerated (0.85); PolyPhen benign (0.377); catalogued as rs866999571; called by muse, mutect2, varscan2
- CSDE1 | c.1493G>A p.R498K (on ENST00000358528 / NM_001007553.3; = p.R467K on NM_007158.6) | Missense Mutation (SNP) | VAF 111/253 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as rs781569478; called by muse, mutect2, varscan2
- CTNND2 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 176/326 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV58893142; called by muse, mutect2, varscan2
- CYP1A2 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 247/488 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59661466; called by muse, mutect2, varscan2
- CYP2U1 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 141/349 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747965749, COSV60549820; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP4A22 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 116/283 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.119); catalogued as rs777084778; called by muse, mutect2, varscan2
- CYP8B1 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 232/443 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1157117737; called by muse, mutect2, varscan2
- DAZAP1 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 246/541 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV99245503; called by muse, mutect2, varscan2
- DAZAP1 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 246/541 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99245465; called by muse, mutect2, varscan2
- DCAF8L1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 199/199 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as rs777162966, COSV71595354; called by muse, mutect2, varscan2
- DCC | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 207/422 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59134782; called by muse, mutect2, varscan2
- DCN | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 130/273 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV50006533; called by muse, mutect2, varscan2
- DDHD1 | c.1963C>T p.L655F (on ENST00000323669; = p.L852F on NM_030637.3) | Missense Mutation (SNP) | VAF 110/292 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV60357397; called by mutect2, varscan2
- DDX28 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 239/552 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as rs1356807601; called by muse, mutect2, varscan2
- DIS3L | c.1132C>T p.R378* (on ENST00000319212 / NM_001143688.3; = p.R295* on NM_133375.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 137/322 reads (43%) | catalogued as rs893215526, COSV59911391; called by muse, mutect2, varscan2
- DNAH12 | c.6163G>A p.E2055K (on ENST00000351747; = p.E2074K on NM_001366028.2) | Missense Mutation (SNP) | VAF 133/272 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.239); catalogued as COSV61059637; called by muse, mutect2, varscan2
- DNAH2 | c.6094C>T p.P2032S | Missense Mutation (SNP) | VAF 169/334 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66720706; called by muse, mutect2, varscan2
- DNAH3 | c.7093G>A p.D2365N | Missense Mutation (SNP) | VAF 149/336 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.669); catalogued as COSV54503765; called by muse, mutect2, varscan2
- DNAH9 | c.9122C>T p.P3041L | Missense Mutation (SNP) | VAF 213/422 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52362361; called by muse, mutect2, varscan2
- DRD5 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 150/306 reads (49%) | SIFT tolerated (0.63); PolyPhen benign (0.02); catalogued as COSV100431878; called by muse, mutect2, varscan2
- DYSF | c.6101C>T p.T2034I | Missense Mutation (SNP) | VAF 205/474 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs771663815; called by muse, mutect2, varscan2
- EHHADH | c.1844G>A p.S615N | Missense Mutation (SNP) | VAF 181/375 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1176614097; called by muse, mutect2, varscan2
- ENTPD5 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 187/379 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1453746383; called by muse, mutect2, varscan2
- EPB41L1 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 158/361 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99151643; called by muse, mutect2, varscan2
- EPPIN | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 205/403 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51490972; called by muse, mutect2, varscan2
- EPX | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 164/311 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs755121348, COSV99836352; called by muse, mutect2, varscan2
- ESRRG | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 417/660 reads (63%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.962); catalogued as rs1435255843; called by muse, mutect2, varscan2
- FAT4 | c.14104C>T p.R4702* | Nonsense Mutation (SNP) | VAF 200/391 reads (51%) | catalogued as COSV58690372; called by muse, mutect2, varscan2
- FCRL1 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 283/431 reads (66%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV63826946, COSV63827240; called by muse, mutect2, varscan2
- FGF7 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 173/322 reads (54%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.601); catalogued as rs1195547010, COSV51065826; called by muse, mutect2, varscan2
- FLG | c.8407G>A p.E2803K | Missense Mutation (SNP) | VAF 215/1323 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.082); catalogued as rs370605039; called by muse, mutect2, varscan2
- FLG | c.1928G>A p.R643K | Missense Mutation (SNP) | VAF 485/750 reads (65%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.745); catalogued as rs1291999516, COSV64238885; called by muse, mutect2, varscan2
- FMNL3 | c.685C>T p.L229F | Missense Mutation (SNP) | VAF 145/305 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV53301802; called by muse, mutect2, varscan2
- FOLH1 | c.2207C>T p.A736V | Missense Mutation (SNP) | VAF 134/295 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as rs767480479; called by muse, mutect2, varscan2
- FOLH1 | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 139/316 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs866827421, COSV99923017; called by muse, mutect2, varscan2
- FPR3 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 146/290 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.261); catalogued as COSV59329223; called by muse, mutect2, varscan2
- FTMT | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 324/628 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100360498, COSV58420205; called by muse, mutect2, varscan2
- GABRE | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 220/220 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs867877489, COSV100944370; called by muse, mutect2, varscan2
- GADL1 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 195/427 reads (46%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.898); catalogued as rs1261964623; called by muse, mutect2, varscan2
- GLI3 | c.4432G>A p.E1478K | Missense Mutation (SNP) | VAF 219/450 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1241442383, CM107040; called by muse, mutect2, varscan2
- GPR45 | c.527C>G p.P176R | Missense Mutation (SNP) | VAF 221/466 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as rs374437830; called by muse, mutect2, varscan2
- GRIN2A | c.3304G>A p.E1102K | Missense Mutation (SNP) | VAF 242/525 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.411); catalogued as rs770546037, COSV58030401; called by muse, mutect2, varscan2
- GXYLT1 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 79/206 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.513); catalogued as rs75740340, COSV99789204; called by muse, mutect2, varscan2
- HEATR5A | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 159/320 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324109831; called by muse, mutect2, varscan2
- HLTF | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 171/335 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1420352778; called by muse, mutect2, varscan2
- HPN | c.291G>A p.R97= | Splice Region (SNP) | VAF 165/323 reads (51%) | catalogued as COSV99061007; called by muse, mutect2, varscan2
- HSF2 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 128/267 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs780492445; called by muse, mutect2, varscan2
- HTR1A | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 196/415 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1221106719; called by muse, mutect2, varscan2
- HTR3C | c.926-1G>A p.X309_splice | Splice Site (SNP) | VAF 173/315 reads (55%) | catalogued as rs1182784613; called by muse, mutect2, varscan2
- IGLV8-61 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 247/458 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV101135150; called by muse, mutect2, varscan2
- IL12A | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 128/291 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as rs933440333; called by muse, mutect2, varscan2
- ILDR1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 219/452 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.339); catalogued as COSV56549679; called by muse, mutect2, varscan2
- INTS5 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 238/467 reads (51%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.034); catalogued as rs1042930641; called by muse, mutect2, varscan2
- JAK1 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 145/357 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV61093408; called by muse, mutect2, varscan2
- JAML | c.550C>T p.R184C (on ENST00000356289 / NM_001098526.2; = p.R174C on NM_153206.3) | Missense Mutation (SNP) | VAF 112/222 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs774147626, COSV52627117, COSV52627225; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2824C>T p.P942S | Missense Mutation (SNP) | VAF 174/360 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs562638505; called by muse, mutect2, varscan2
- KCNQ1 | c.1251G>A p.V417= | Splice Region (SNP) | VAF 199/369 reads (54%) | catalogued as rs1369698000; called by muse, mutect2, varscan2
- KCNS1 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 316/563 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1407855838; called by muse, mutect2, varscan2
- KCNT2 | c.3206G>A p.G1069E | Missense Mutation (SNP) | VAF 112/332 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as rs751522470; called by muse, mutect2, varscan2
- KCNV1 | c.1495T>A p.W499R | Missense Mutation (SNP) | VAF 114/217 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52085373; called by muse, mutect2, varscan2
- KDM2B | c.3368G>A p.R1123Q | Missense Mutation (SNP) | VAF 178/398 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as rs781826750; called by muse, mutect2, varscan2
- KHDRBS3 | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 102/247 reads (41%) | catalogued as rs777562123; called by muse, mutect2, varscan2
- KIAA1109 | c.7645T>G p.Y2549D | Missense Mutation (SNP) | VAF 240/474 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1185081263; called by muse, mutect2, varscan2
- KLRK1 | c.203T>A p.I68N | Missense Mutation (SNP) | VAF 106/220 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs377167821; called by muse, mutect2
- KMT2A | c.7639C>T p.P2547S | Missense Mutation (SNP) | VAF 163/354 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.162); catalogued as rs1555046723; called by muse, mutect2, varscan2
- KMT5B | c.2645G>A p.R882K | Missense Mutation (SNP) | VAF 87/180 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1233285083; called by muse, mutect2, varscan2
- KRT24 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 184/391 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs760797312; called by muse, mutect2, varscan2
- KRT84 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 215/466 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.027); catalogued as rs1457316224; called by muse, mutect2, varscan2
- L1TD1 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 187/371 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.087); catalogued as rs752701856, COSV63133360; called by muse, mutect2, varscan2
- LAMB4 | c.3890C>T p.S1297F | Missense Mutation (SNP) | VAF 120/256 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs761572743, COSV52732020; called by muse, mutect2, varscan2
- LENG9 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 280/540 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1349593267; called by muse, mutect2, varscan2
- LRP1B | c.3787A>G p.I1263V | Missense Mutation (SNP) | VAF 81/209 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs1012095559; called by muse, mutect2, varscan2
- LRRC43 | c.1702G>A p.G568S | Missense Mutation (SNP) | VAF 259/560 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as rs1412131690; called by muse, mutect2, varscan2
- LRRC45 | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 93/227 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs1265923233; called by muse, mutect2, varscan2
- MAGEB16 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 267/267 reads (100%) | SIFT tolerated (0.35); PolyPhen benign (0.037); catalogued as COSV101303345; called by muse, mutect2, varscan2
- MAP1A | c.4817C>T p.A1606V | Missense Mutation (SNP) | VAF 109/267 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as rs750022307, COSV55813403; called by muse, mutect2, varscan2
- MAP4K3 | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 125/271 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55716906; called by muse, mutect2, varscan2
- MBD3L1 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 116/251 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771170768, COSV59775876; called by muse, mutect2, varscan2
- MBD5 | c.3372T>A p.S1124R | Missense Mutation (SNP) | VAF 236/719 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1246420113; called by muse, mutect2, varscan2
- MEI4 | c.512G>A p.R171K | Missense Mutation (SNP) | VAF 137/291 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs527596466; called by muse, mutect2, varscan2
- MGAT4C | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 119/249 reads (48%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1222715246, COSV59830124, COSV59831777; called by muse, mutect2, varscan2
- MICAL2 | c.3116C>T p.A1039V | Missense Mutation (SNP) | VAF 195/408 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); catalogued as rs144708456; called by muse, mutect2, varscan2
- MMP11 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 345/710 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as rs780729049; called by muse, mutect2, varscan2
- MORC1 | c.1237A>G p.N413D | Missense Mutation (SNP) | VAF 153/291 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as rs373695498; called by muse, mutect2, varscan2
- MROH2A | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 165/363 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs766826150, COSV67682690; called by muse, mutect2, varscan2
- MROH2B | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 97/224 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1451889213, COSV101270575, COSV101270679; called by muse, mutect2, varscan2
- MS4A8 | c.645C>A p.S215R | Missense Mutation (SNP) | VAF 108/240 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as rs756117147; called by muse, mutect2, varscan2
- MTARC1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 168/464 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs771876954; called by muse, mutect2, varscan2
- MUC16 | c.33578C>T p.S11193L | Missense Mutation (SNP) | VAF 143/329 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.909); catalogued as COSV67495392; called by muse, mutect2, varscan2
- MUC16 | c.29907T>G p.S9969R | Missense Mutation (SNP) | VAF 179/393 reads (46%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as COSV67475229; called by muse, mutect2, varscan2
- MUC16 | c.20288G>A p.G6763E | Missense Mutation (SNP) | VAF 248/502 reads (49%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.033); catalogued as rs369370967; called by muse, mutect2, varscan2
- MUC16 | c.16105C>T p.P5369S | Missense Mutation (SNP) | VAF 218/434 reads (50%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.062); catalogued as COSV67478194; called by muse, mutect2, varscan2
- MUC16 | c.13150G>A p.G4384R | Missense Mutation (SNP) | VAF 177/398 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.1); catalogued as COSV101200644; called by muse, mutect2, varscan2
- MYCBPAP | c.468G>A p.Q156= | Splice Region (SNP) | VAF 104/241 reads (43%) | catalogued as COSV60412055; called by muse, mutect2, varscan2
- MYH11 | c.3002G>A p.R1001Q | Missense Mutation (SNP) | VAF 114/218 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs376622843; called by muse, mutect2, varscan2
- MYH13 | c.2723G>A p.R908Q | Missense Mutation (SNP) | VAF 129/312 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.975); catalogued as rs572952027; called by muse, mutect2, varscan2
- MYH4 | c.2588C>T p.T863I | Missense Mutation (SNP) | VAF 208/418 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs766143426, COSV55127608; called by muse, mutect2, varscan2
- MYH4 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 157/326 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV55111317; called by muse, mutect2, varscan2
- MYH8 | c.2430G>A p.R810= | Splice Region (SNP) | VAF 117/230 reads (51%) | catalogued as rs1478940960, COSV67967922; called by muse, mutect2, varscan2
- MYOM1 | c.3190C>T p.H1064Y | Missense Mutation (SNP) | VAF 187/360 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755409090; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NBEA | c.6049G>A p.E2017K | Missense Mutation (SNP) | VAF 118/260 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59762759; called by muse, mutect2, varscan2
- NBEAL2 | c.2717C>T p.P906L | Missense Mutation (SNP) | VAF 196/443 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.127); catalogued as rs1190003464; called by muse, mutect2, varscan2
- NBL1 | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 167/392 reads (43%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.991); catalogued as rs1410289295; called by muse, varscan2
- NBPF11 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 58/648 reads (9%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.992); catalogued as rs1411507605; called by muse, mutect2, varscan2
- NCKAP1L | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 177/349 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53203336; called by muse, mutect2, varscan2
- NCKAP5L | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 261/495 reads (53%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.885); catalogued as rs1266010564; called by muse, mutect2, varscan2
- NEU4 | c.175G>A p.G59S (on ENST00000391969 / NM_001167602.3; = p.G71S on NM_080741.4) | Missense Mutation (SNP) | VAF 244/497 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs1028727458; called by muse, mutect2, varscan2
- NFKBIE | c.1447C>T p.L483F (on ENST00000275015; = p.L344F on NM_004556.3) | Missense Mutation (SNP) | VAF 84/203 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as rs1561912982; called by muse, mutect2, varscan2
- NLRP13 | c.246G>A p.W82* | Nonsense Mutation (SNP) | VAF 181/369 reads (49%) | catalogued as COSV100738207; called by muse, mutect2, varscan2
- NLRP2 | c.2899C>T p.P967S | Missense Mutation (SNP) | VAF 191/432 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs375615677; called by muse, mutect2, varscan2
- NLRP3 | c.1272G>A p.M424I | Missense Mutation (SNP) | VAF 251/787 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV60229257; called by muse, mutect2, varscan2
- NMUR2 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 207/474 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1352413085, COSV54923197; called by muse, mutect2, varscan2
- NOBOX | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 199/387 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV99779568; called by muse, mutect2, varscan2
- NODAL | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 146/317 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1316642787; called by muse, mutect2, varscan2
- NPHS2 | c.537C>T p.I179= | Splice Region (SNP) | VAF 84/256 reads (33%) | catalogued as rs370260554; called by muse, mutect2, varscan2
- NTRK1 | c.360-1G>A p.X120_splice | Splice Site (SNP) | VAF 140/413 reads (34%) | catalogued as COSV100693566; called by muse, mutect2, varscan2
- OLFM4 | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 179/378 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV54578391; called by muse, mutect2, varscan2
- OR10J3 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 331/505 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1251768496; called by muse, mutect2, varscan2
- OR10P1 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 220/446 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs374603359, COSV59006615; called by muse, mutect2, varscan2
- OR2A2 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 163/352 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV68871596, COSV68871682; called by muse, mutect2, varscan2
- OR4A15 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 208/439 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1428184028, COSV59035680; called by muse, mutect2, varscan2
- OR4A15 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 204/417 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.766); catalogued as rs1565113120, COSV59035504; called by muse, mutect2, varscan2
- OR4Q2 | c.525+1G>A | Missense Mutation (SNP) | VAF 169/358 reads (47%) | catalogued as rs895174410; called by muse, mutect2, varscan2
- OR51B6 | c.855G>A p.M285I | Missense Mutation (SNP) | VAF 169/364 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs267602948; called by muse, mutect2
- OR52B6 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 210/429 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61447187; called by muse, mutect2, varscan2
- OR5H14 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 148/260 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as rs752967855, COSV71194648, COSV71194693; called by muse, mutect2, varscan2
- OR6K6 | c.599A>G p.N200S (on ENST00000368144; = p.N176S on NM_001005184.1) | Missense Mutation (SNP) | VAF 258/760 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs1332237429, COSV63744139; called by muse, mutect2, varscan2
- OR7G1 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 191/370 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53319147; called by muse, mutect2, varscan2
- OR7G3 | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 242/496 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs200054594; called by muse, mutect2, varscan2
- OR8U1 | c.254T>C p.F85S | Missense Mutation (SNP) | VAF 210/472 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV56413879; called by muse, varscan2
- OTOL1 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 195/385 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.516); catalogued as rs1429646440; called by muse, mutect2, varscan2
- OTOP1 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 222/467 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs140788465; called by muse, mutect2, varscan2
- OTUD7A | c.892G>A p.G298S (on ENST00000307050 / NM_001382637.1; = p.G291S on NM_130901.3) | Missense Mutation (SNP) | VAF 193/430 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1167780057, COSV61037837; called by muse, mutect2, varscan2
- PCDH15 | c.2870G>A p.G957E | Missense Mutation (SNP) | VAF 107/196 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV57281943; called by muse, mutect2, varscan2
- PCDHB4 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 207/400 reads (52%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.179); catalogued as COSV52020239, COSV99522329; called by muse, mutect2, varscan2
- PCDHGA1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 175/367 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as rs898742572, COSV65294827; called by muse, mutect2, varscan2
- PCDHGB5 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 154/353 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366423528; called by muse, mutect2, varscan2
- PCNX4 | c.1148C>T p.S383F (on ENST00000406854 / NM_001330177.2; = p.S149F on NM_022495.5) | Missense Mutation (SNP) | VAF 154/276 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.44); catalogued as rs1305310519, COSV58302415; called by muse, mutect2, varscan2
- PCSK1 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 201/431 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.142); catalogued as COSV60737491; called by muse, mutect2, varscan2
- PDE3A | c.2111G>A p.G704E | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV62968633; called by muse, varscan2
- PDHA2 | c.636G>A p.W212* | Nonsense Mutation (SNP) | VAF 188/401 reads (47%) | catalogued as COSV54778995; called by muse, mutect2, varscan2
- PER2 | c.2495C>T p.S832L | Missense Mutation (SNP) | VAF 293/604 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1008195179; called by muse, mutect2, varscan2
- PES1 | c.799T>A p.L267M | Missense Mutation (SNP) | VAF 208/409 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0.045); catalogued as COSV58828614; called by muse, mutect2, varscan2
- PIGR | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 238/715 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs748382437; called by muse, mutect2, varscan2
- PIWIL3 | c.2533G>A p.G845S | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1569093103; called by muse, mutect2, varscan2
- PLCH1 | c.3425G>A p.R1142K (on ENST00000340059 / NM_001130960.2; = p.R1134K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 157/334 reads (47%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as COSV58205006; called by muse, mutect2, varscan2
- PLCXD2 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 199/426 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.736); catalogued as rs377101481, COSV67342400; called by muse, mutect2, varscan2
- PLEKHG5 | c.706C>T p.P236S (on ENST00000400915 / NM_001042663.3; = p.P199S on NM_020631.6) | Missense Mutation (SNP) | VAF 164/307 reads (53%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.948); catalogued as rs1157862488; called by muse, mutect2, varscan2
- PLXNA4 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 191/411 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs267601293, COSV58119180; called by muse, mutect2, varscan2
- POU6F2 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 220/509 reads (43%) | catalogued as COSV68883041; called by muse, mutect2, varscan2
- PPP1R21 | c.1246C>T p.L416F | Missense Mutation (SNP) | VAF 159/368 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.633); catalogued as rs1396493130; called by muse, mutect2, varscan2
- PPP1R37 | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 292/589 reads (50%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.945); catalogued as rs757743404; called by muse, mutect2, varscan2
- PRAG1 | c.2389C>T p.P797S | Missense Mutation (SNP) | VAF 270/518 reads (52%) | SIFT tolerated (0.63); PolyPhen benign (0.099); catalogued as COSV58161076; called by muse, mutect2, varscan2
- PRB4 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 293/523 reads (56%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs374921001, COSV54395119; called by muse, mutect2
- PREX2 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 213/427 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs868582467, COSV55755180; called by muse, mutect2, varscan2
- PRRG3 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 377/378 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as rs950659306, COSV64851468; called by muse, mutect2, varscan2
- PTCD1 | c.1553C>G p.A518G | Missense Mutation (SNP) | VAF 244/496 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as COSV99464673; called by muse, mutect2, varscan2
- PTPRU | c.2164C>T p.R722C | Missense Mutation (SNP) | VAF 184/375 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749851774; called by muse, mutect2, varscan2
- RAD54L2 | c.4207C>T p.P1403S | Missense Mutation (SNP) | VAF 254/532 reads (48%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs1234750870, COSV99621493; called by muse, mutect2, varscan2
- RANBP3L | c.903+1G>A p.X301_splice | Splice Site (SNP) | VAF 133/320 reads (42%) | catalogued as COSV56955487; called by muse, mutect2, varscan2
- RCSD1 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 238/760 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.154); catalogued as COSV63257769; called by muse, mutect2, varscan2
- RFX6 | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 124/269 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60584285; called by muse, mutect2, varscan2
- RFX6 | c.1749G>A p.M583I | Missense Mutation (SNP) | VAF 173/361 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1326581635, COSV60587925; called by muse, mutect2, varscan2
- RGSL1 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 123/420 reads (29%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.448); catalogued as rs1327737019, COSV99679401; called by muse, mutect2, varscan2
- RHO | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 208/427 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs200095648; called by muse, mutect2, varscan2
- RHOH | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 181/392 reads (46%) | catalogued as rs1416692929, COSV67805097; called by muse, mutect2, varscan2
- RHOT1 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 158/365 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.042); catalogued as rs1251712158; called by muse, mutect2, varscan2
- RIPOR2 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 125/257 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52418115; called by muse, mutect2, varscan2
- RUVBL2 | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 157/343 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780165337; called by muse, mutect2, varscan2
- RYR3 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 187/379 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs747820461, COSV66786499; called by muse, mutect2, varscan2
- SACS | c.7907C>T p.P2636L | Missense Mutation (SNP) | VAF 221/221 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101207251; called by muse, mutect2, varscan2
- SAMHD1 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 151/333 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1234364779; called by muse, mutect2, varscan2
- SDK2 | c.4423C>T p.R1475* | Nonsense Mutation (SNP) | VAF 131/272 reads (48%) | catalogued as rs866006487; called by muse, mutect2, varscan2
- SDK2 | c.4422C>G p.F1474L | Missense Mutation (SNP) | VAF 131/268 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.181); catalogued as rs1487436688; called by muse, mutect2, varscan2
- SEMG1 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 120/238 reads (50%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.96); catalogued as COSV54871876, COSV54872313; called by muse, mutect2, varscan2
- SFI1 | c.2093G>A p.R698Q (on ENST00000400288 / NM_001007467.3; = p.R667Q on NM_014775.4) | Missense Mutation (SNP) | VAF 169/343 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs753089246, COSV101191831; called by muse, mutect2, varscan2
- SH3BP2 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 360/738 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); catalogued as rs867169595; called by muse, mutect2, varscan2
- SHBG | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 184/356 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.165); catalogued as rs183272852; called by muse, mutect2, varscan2
- SHC2 | c.981G>T p.W327C | Missense Mutation (SNP) | VAF 187/397 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs532732139, COSV52747911; called by muse, mutect2, varscan2
- SIPA1L3 | c.4349C>T p.P1450L | Missense Mutation (SNP) | VAF 241/489 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as rs548838198, COSV99727390; called by muse, mutect2, varscan2
- SIRT7 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 153/310 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs567589929, COSV100155711, COSV58711732; called by muse, mutect2, varscan2
- SLC10A2 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 201/395 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55361364; called by muse, mutect2, varscan2
- SLC16A12 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 129/129 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100369994, COSV57950826; called by muse, mutect2, varscan2
- SLC17A7 | c.1595G>A p.G532E | Missense Mutation (SNP) | VAF 164/391 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs990263659, COSV55546290, COSV55547088; called by muse, mutect2, varscan2
- SLC28A1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 113/289 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs768377268, COSV54476945; called by muse, mutect2, varscan2
- SLC39A2 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 211/428 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs138590006; called by muse, mutect2, varscan2
- SPEG | c.3250G>A p.D1084N | Missense Mutation (SNP) | VAF 224/501 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs759841206; called by muse, mutect2, varscan2
- SPHKAP | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 200/383 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs1487343994; called by muse, mutect2, varscan2
- SPOCD1 | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 242/476 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.188); catalogued as rs757160383, COSV57096392; called by muse, mutect2, varscan2
- ST8SIA3 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 143/301 reads (48%) | catalogued as COSV60653415; called by muse, mutect2, varscan2
- STYX | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 101/227 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV63463579; called by muse, mutect2, varscan2
- SV2A | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 161/488 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100975127; called by muse, mutect2, varscan2
- SYNGAP1 | c.2230C>T p.Q744* | Nonsense Mutation (SNP) | VAF 367/707 reads (52%) | catalogued as rs1554121947; called by muse, mutect2, varscan2
- SYT1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 114/255 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54039227, COSV99693692; called by muse, mutect2, varscan2
- SYTL2 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.085); catalogued as COSV60363612; called by muse, mutect2, varscan2
- TAF1C | c.2398C>T p.P800S | Missense Mutation (SNP) | VAF 289/615 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.121); catalogued as rs757737958, COSV100499593; called by muse, mutect2, varscan2
- TBC1D4 | c.3575C>T p.S1192F | Missense Mutation (SNP) | VAF 168/362 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs762526748; called by muse, mutect2, varscan2
- TFDP2 | c.362G>A p.R121Q (on ENST00000489671 / NM_001178139.2; = p.R60Q on NM_006286.5) | Missense Mutation (SNP) | VAF 116/225 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs1298190375; called by muse, mutect2, varscan2
- THSD4 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 107/231 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as rs1285714444, COSV99964731; called by muse, mutect2, varscan2
- TIAM2 | c.3239G>A p.R1080Q | Missense Mutation (SNP) | VAF 172/438 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.08); catalogued as rs543173995, COSV51638119; called by muse, mutect2
- TIMM44 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 170/375 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs778758579, COSV54490251; called by muse, mutect2, varscan2
- TLR3 | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 144/318 reads (45%) | catalogued as COSV57167730; called by muse, varscan2
- TLR5 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 162/517 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV60561272; called by muse, mutect2, varscan2
- TMEM131L | c.3404G>A p.R1135K | Missense Mutation (SNP) | VAF 90/187 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs773923664; called by muse, mutect2, varscan2
- TMEM132D | c.2870G>A p.G957E | Missense Mutation (SNP) | VAF 193/412 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs764597587, COSV101243030; called by muse, varscan2
- TMPRSS7 | c.908C>T p.S303F (on ENST00000452346; = p.S177F on NM_001042575.2) | Missense Mutation (SNP) | VAF 160/371 reads (43%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.961); catalogued as COSV101340073; called by muse, mutect2, varscan2
- TNFRSF1A | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 218/471 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.442); catalogued as rs1473547216; called by muse, mutect2, varscan2
- TPH2 | c.426G>A p.W142* | Nonsense Mutation (SNP) | VAF 121/237 reads (51%) | catalogued as COSV61590776; called by muse, mutect2, varscan2
- TRBC2 | c.148A>G p.K50E | Missense Mutation (SNP) | VAF 206/461 reads (45%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.62); catalogued as rs1554512573; called by muse, mutect2, varscan2
- TRIM17 | c.1391G>A p.G464D | Missense Mutation (SNP) | VAF 134/447 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1398441920; called by muse, mutect2, varscan2
- TRIM61 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 151/301 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.37); catalogued as rs1238874561; called by muse, mutect2, varscan2
- TRIOBP | c.3910C>T p.R1304C | Missense Mutation (SNP) | VAF 234/458 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs550274094; called by muse, mutect2, varscan2
- TRPA1 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 152/320 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV51566183; called by muse, mutect2, varscan2
- UGT2A3 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 192/433 reads (44%) | catalogued as COSV52360874; called by muse, mutect2, varscan2
- UNC13C | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 169/347 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.212); catalogued as rs1451262581, COSV52912943; called by muse, mutect2, varscan2
- VPS13C | c.3685G>T p.V1229L (on ENST00000644861 / NM_020821.3; = p.V1186L on NM_017684.5) | Missense Mutation (SNP) | VAF 164/312 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs766371434; called by muse, mutect2, varscan2
- VPS13D | c.3373T>G p.F1125V | Missense Mutation (SNP) | VAF 94/207 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50623202; called by muse, mutect2, varscan2
- WDR47 | c.2693C>T p.T898I (on ENST00000369962 / NM_001142551.2; = p.T899I on NM_014969.5) | Missense Mutation (SNP) | VAF 192/400 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV63059366; called by muse, mutect2, varscan2
- WDR86 | c.727-8C>T | Splice Region (SNP) | VAF 249/511 reads (49%) | catalogued as rs968732791, COSV100561217; called by muse, mutect2, varscan2
- WIF1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 146/322 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV54131993; called by muse, mutect2
- YME1L1 | c.935C>T p.P312L (on ENST00000326799 / NM_139312.3; = p.P255L on NM_014263.4) | Missense Mutation (SNP) | VAF 107/107 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100463436; called by muse, mutect2, varscan2
- ZBTB49 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 138/307 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs1265588413; called by muse, mutect2, varscan2
- ZC3H13 | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 188/376 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs754240291, COSV54450719; called by muse, mutect2, varscan2
- ZFHX4 | c.4571G>A p.R1524K | Missense Mutation (SNP) | VAF 181/402 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV50597469; called by muse, mutect2, varscan2
- ZIC1 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 320/674 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51557666; called by muse, mutect2, varscan2
- ZNF253 | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 120/277 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63037253; called by muse, mutect2, varscan2
- ZNF304 | c.1489C>T p.H497Y | Missense Mutation (SNP) | VAF 225/434 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV99988760; called by muse, mutect2, varscan2
- ZNF420 | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 151/355 reads (43%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.882); catalogued as rs775994644, COSV58492526; called by muse, mutect2, varscan2
- ZNF462 | c.3107C>T p.S1036L | Missense Mutation (SNP) | VAF 400/402 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs745724742, COSV52936186; called by muse, mutect2, varscan2
- ZNF469 | c.9715C>T p.P3239S (on ENST00000437464; = p.P3267S on NM_001367624.2) | Missense Mutation (SNP) | VAF 260/603 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs528159004; called by muse, mutect2, varscan2
- ZNF469 | c.9716C>T p.P3239L (on ENST00000437464; = p.P3267L on NM_001367624.2) | Missense Mutation (SNP) | VAF 265/607 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1205639918; called by muse, mutect2, varscan2
- ZNF479 | c.1454G>A p.R485K | Missense Mutation (SNP) | VAF 142/278 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV58637819, COSV58643680; called by muse, mutect2, varscan2
- ZNF681 | c.826C>T p.H276Y | Missense Mutation (SNP) | VAF 197/443 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV101267409; called by muse, mutect2
- ZNF681 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 138/265 reads (52%) | SIFT tolerated (0.66); PolyPhen benign (0.039); catalogued as COSV101267392; called by muse, mutect2, varscan2
- AADAC | c.846T>A p.N282K | Missense Mutation (SNP) | VAF 146/308 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC9 | c.4625C>T p.S1542F | Missense Mutation (SNP) | VAF 131/311 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- ACAD10 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 111/222 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACTR1B | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 215/446 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADAD1 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 148/303 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2837G>A p.W946* | Nonsense Mutation (SNP) | VAF 153/324 reads (47%) | called by muse, mutect2, varscan2
- ADAMTSL3 | c.2838G>A p.W946* | Nonsense Mutation (SNP) | VAF 153/325 reads (47%) | called by muse, mutect2, varscan2
- ADGRF2 | c.752C>T p.S251F (on ENST00000296862 / NM_001368115.2; = p.S183F on NM_153839.7) | Missense Mutation (SNP) | VAF 129/267 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADPRH | c.492C>A p.H164Q | Missense Mutation (SNP) | VAF 223/475 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADPRHL1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 184/425 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- AFAP1 | c.655A>T p.I219F | Missense Mutation (SNP) | VAF 207/399 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- AFF1 | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 205/436 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGBL1 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 152/324 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- AJUBA | c.1322T>G p.F441C | Missense Mutation (SNP) | VAF 158/329 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ALCAM | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 154/312 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- AQP4 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 154/351 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- ARAP2 | c.979A>T p.N327Y | Missense Mutation (SNP) | VAF 97/204 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ARHGEF10L | c.1795G>C p.V599L | Missense Mutation (SNP) | VAF 198/410 reads (48%) | SIFT tolerated (0.99); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- ARHGEF15 | c.1915G>A p.G639R | Missense Mutation (SNP) | VAF 239/477 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF15 | c.1916G>A p.G639E | Missense Mutation (SNP) | VAF 240/482 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATN1 | c.2077G>A p.G693R | Missense Mutation (SNP) | VAF 374/743 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- BCAS3 | c.2422C>T p.P808S (on ENST00000390652 / NM_001353144.2; = p.P793S on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 178/347 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- BICRAL | c.1273C>T p.L425F | Missense Mutation (SNP) | VAF 185/401 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- BLOC1S5 | c.152C>G p.P51R | Missense Mutation (SNP) | VAF 79/229 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- BNIPL | c.662G>A p.C221Y | Missense Mutation (SNP) | VAF 151/452 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRSK1 | c.612G>A p.G204= | Splice Region (SNP) | VAF 181/398 reads (45%) | called by muse, mutect2, varscan2
- BRSK1 | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 195/391 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRSK2 | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 219/445 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- C3orf20 | c.2507C>T p.S836F | Missense Mutation (SNP) | VAF 134/305 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CABP4 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 127/290 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CAMSAP2 | c.767G>T p.C256F (on ENST00000236925 / NM_001297707.2; = p.C245F on NM_203459.3) | Missense Mutation (SNP) | VAF 364/598 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CBLL2 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 244/244 reads (100%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC93 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 179/356 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCNB3 | c.3521C>T p.S1174F | Missense Mutation (SNP) | VAF 91/92 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CD55 | c.586T>A p.L196I | Missense Mutation (SNP) | VAF 104/315 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CD5L | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 395/605 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH10 | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 206/415 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, varscan2
- CDH11 | c.1748G>T p.S583I | Missense Mutation (SNP) | VAF 229/522 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- CDH13 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 196/399 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH23 | c.2456C>T p.P819L | Missense Mutation (SNP) | VAF 239/513 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CEMIP | c.137G>A p.W46* | Nonsense Mutation (SNP) | VAF 192/422 reads (45%) | called by muse, mutect2, varscan2
- CENPC | c.1579C>A p.P527T | Missense Mutation (SNP) | VAF 128/261 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEP290 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 138/274 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- CFAP54 | c.3077T>C p.V1026A | Missense Mutation (SNP) | VAF 94/176 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CGN | c.3155C>T p.S1052F | Missense Mutation (SNP) | VAF 159/562 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CHAT | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 180/344 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHST3 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 225/501 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CKAP4 | c.1307C>T p.S436F | Missense Mutation (SNP) | VAF 221/430 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- CKM | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 149/316 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CLCN3 | c.807A>T p.L269F | Missense Mutation (SNP) | VAF 141/336 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- CNKSR3 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 187/359 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- CNOT6L | c.361C>T p.L121F (on ENST00000504123 / NM_001286790.2; = p.L116F on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/228 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- COL15A1 | c.3319C>T p.P1107S | Missense Mutation (SNP) | VAF 271/271 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- COL1A1 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 188/410 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.068); called by muse, mutect2
- COL5A2 | c.3571G>A p.G1191R | Missense Mutation (SNP) | VAF 134/292 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A2 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 196/355 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPNE3 | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 130/261 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- CRB1 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 159/485 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- CSMD2 | c.3404G>A p.G1135E | Missense Mutation (SNP) | VAF 180/377 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSNKA2IP | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 162/350 reads (46%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CUX1 | c.4392_4408del p.A1465Lfs*80 | Frame Shift Del (DEL) | VAF 162/406 reads (40%) | called by pindel, varscan2
- CUZD1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 83/83 reads (100%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CWF19L1 | c.1201A>T p.K401* | Nonsense Mutation (SNP) | VAF 148/148 reads (100%) | called by muse, mutect2, varscan2
- CXorf21 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 248/249 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- CYP11A1 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 184/416 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- DCAF10 | c.827A>T p.N276I | Missense Mutation (SNP) | VAF 85/85 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHX30 | c.-123G>A | Splice Region (SNP) | VAF 160/329 reads (49%) | called by muse, mutect2, varscan2
- DMRTC1 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 109/225 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- DSP | c.4066G>A p.D1356N | Missense Mutation (SNP) | VAF 124/279 reads (44%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- E2F8 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 181/382 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EIF4E1B | c.691A>G p.K231E | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- ELOA3D | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 238/927 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ESPNL | c.1400C>T p.S467F | Missense Mutation (SNP) | VAF 265/531 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EVC | c.1685A>T p.Q562L | Missense Mutation (SNP) | VAF 189/381 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- FAM205A | c.1975G>A p.A659T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by mutect2, varscan2
- FAM214B | c.1577C>T p.T526I | Missense Mutation (SNP) | VAF 188/188 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- FAR1 | c.1490T>C p.V497A | Missense Mutation (SNP) | VAF 114/242 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- FER1L5 | c.1655-1G>A p.X552_splice (on ENST00000623019; = p.X557_splice on NM_001293083.2) | Splice Site (SNP) | VAF 114/214 reads (53%) | called by muse, mutect2, varscan2
- FES | c.1789C>T p.P597S | Missense Mutation (SNP) | VAF 166/403 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- FEZ1 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 134/274 reads (49%) | called by muse, mutect2, varscan2
- FGD2 | c.685-1G>A p.X229_splice | Splice Site (SNP) | VAF 130/241 reads (54%) | called by muse, mutect2, varscan2
- FOXK2 | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 150/275 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRG2C | c.677A>C p.Y226S | Missense Mutation (SNP) | VAF 202/1359 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- FSTL5 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 133/268 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- FXYD6 | c.62C>A p.A21D | Missense Mutation (SNP) | VAF 154/316 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- FYN | c.953T>C p.M318T | Missense Mutation (SNP) | VAF 182/360 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GABRB1 | c.836-1G>A p.X279_splice | Splice Site (SNP) | VAF 86/182 reads (47%) | called by muse, mutect2, varscan2
- GAGE10 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 33/458 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- GALR3 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 289/520 reads (56%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- GCKR | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 176/379 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- GIMAP6 | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 233/468 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- GOLGA3 | c.1333C>T p.L445F | Missense Mutation (SNP) | VAF 171/354 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GOLGB1 | c.8856C>T p.L2952= | Splice Region (SNP) | VAF 113/234 reads (48%) | called by muse, mutect2, varscan2
- GP1BA | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 190/394 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- GPD2 | c.1507G>T p.D503Y | Missense Mutation (SNP) | VAF 122/267 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GPR149 | c.1952C>T p.S651F | Missense Mutation (SNP) | VAF 238/470 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR182 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 222/494 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GRIN2D | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 309/604 reads (51%) | SIFT tolerated (0.67); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- GRM1 | c.2287C>T p.L763F | Missense Mutation (SNP) | VAF 204/423 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HBA1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 152/637 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HS3ST6 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 310/667 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2
- HSD17B8 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 214/438 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTR1E | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 142/390 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HYDIN | c.9263C>T p.S3088F | Missense Mutation (SNP) | VAF 89/216 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- HYDIN | c.964C>T p.H322Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by mutect2, varscan2
- IBTK | c.2872A>G p.I958V | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFNA13 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 46/73 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- IFNE | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 96/96 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGKV6D-41 | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 73/138 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- IGSF9B | c.3772C>T p.P1258S | Missense Mutation (SNP) | VAF 351/693 reads (51%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- INAVA | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 148/478 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- INPPL1 | c.1586G>T p.S529I | Missense Mutation (SNP) | VAF 170/394 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IRS2 | c.925T>G p.S309A | Missense Mutation (SNP) | VAF 278/568 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KCNRG | c.281T>A p.L94Q | Missense Mutation (SNP) | VAF 158/344 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KCTD9 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 130/284 reads (46%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- KDM5B | c.1642C>T p.L548F | Missense Mutation (SNP) | VAF 158/567 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- KIAA1671 | c.3584G>A p.R1195K | Missense Mutation (SNP) | VAF 137/324 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- KLK1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 188/460 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.764); called by muse, mutect2
- KRBA1 | c.2662C>A p.L888M | Missense Mutation (SNP) | VAF 290/555 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRTAP5-10 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 185/371 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- LCE6A | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 341/485 reads (70%) | SIFT tolerated (0.08); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- LCK | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 172/384 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- LRRC43 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 232/504 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC69 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 128/274 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MANBA | c.2147C>T p.S716F (on ENST00000642252; = p.S670F on NM_005908.4) | Missense Mutation (SNP) | VAF 121/249 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP1A | c.2533G>A p.V845M | Missense Mutation (SNP) | VAF 247/433 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MARF1 | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 215/444 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- MBOAT4 | c.1087T>C p.S363P | Missense Mutation (SNP) | VAF 168/317 reads (53%) | SIFT tolerated (0.94); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MED23 | c.3262C>T p.P1088S | Missense Mutation (SNP) | VAF 164/311 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- MEX3D | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 303/657 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- MGAM | c.2791G>A p.D931N | Missense Mutation (SNP) | VAF 124/268 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MLXIPL | c.1929C>A p.D643E | Missense Mutation (SNP) | VAF 174/364 reads (48%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MMP27 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 171/384 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MOV10L1 | c.2967G>C p.R989S | Missense Mutation (SNP) | VAF 237/468 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MPP7 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 134/134 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC16 | c.43352C>T p.P14451L | Missense Mutation (SNP) | VAF 111/205 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC2 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 165/353 reads (47%) | SIFT deleterious (0.05); called by muse, mutect2, varscan2
- MUC22 | c.4388C>T p.S1463F | Missense Mutation (SNP) | VAF 248/506 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- MYH15 | c.5378G>A p.R1793K | Missense Mutation (SNP) | VAF 179/416 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- MYO10 | c.6002C>T p.S2001F | Missense Mutation (SNP) | VAF 199/441 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYO10 | c.4760C>T p.P1587L | Missense Mutation (SNP) | VAF 176/422 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MYRFL | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 109/228 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- NBEA | c.5341C>T p.P1781S | Missense Mutation (SNP) | VAF 138/279 reads (49%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- NCAM1 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 132/272 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- NCKIPSD | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 158/335 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- NDUFB4 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 114/271 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEMF | c.109T>A p.Y37N | Missense Mutation (SNP) | VAF 86/187 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NF1 | c.7205C>T p.S2402L (on ENST00000358273 / NM_001042492.3; = p.S2381L on NM_000267.3) | Missense Mutation (SNP) | VAF 88/186 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.056); called by muse, varscan2
- NLRP5 | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 241/516 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- NOBOX | c.48G>A p.W16* | Nonsense Mutation (SNP) | VAF 165/378 reads (44%) | called by muse, mutect2
- NPAT | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 155/357 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NRP2 | c.2786C>T p.S929F (on ENST00000360409 / NM_201266.2; = p.S924F on NM_003872.3) | Missense Mutation (SNP) | VAF 120/240 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- NUP153 | c.2272C>T p.L758F | Missense Mutation (SNP) | VAF 162/361 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NWD1 | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 181/415 reads (44%) | called by muse, mutect2, varscan2
- NXPE2 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 84/199 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OCIAD2 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 118/272 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OCM | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 91/240 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ONECUT3 | c.585G>A p.M195I | Missense Mutation (SNP) | VAF 184/363 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ONECUT3 | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 183/362 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OPN5 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 182/360 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2M2 | c.51C>G p.I17M | Missense Mutation (SNP) | VAF 117/468 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- OR52L1 | c.821T>A p.I274N | Missense Mutation (SNP) | VAF 181/354 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- OSBPL7 | c.2095C>T p.H699Y | Missense Mutation (SNP) | VAF 221/515 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OTOF | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 164/360 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- OXLD1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 237/478 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PABPC4 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 183/408 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PAK6 | c.1226G>A p.S409N | Missense Mutation (SNP) | VAF 278/517 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PALB2 | c.2591C>T p.P864L | Missense Mutation (SNP) | VAF 130/228 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PCCA | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 206/450 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PCDH12 | c.1656G>A p.W552* | Nonsense Mutation (SNP) | VAF 216/439 reads (49%) | called by muse, mutect2, varscan2
- PCDHA12 | c.1440G>A p.W480* | Nonsense Mutation (SNP) | VAF 370/790 reads (47%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 122/301 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCM1 | c.2788A>T p.N930Y | Missense Mutation (SNP) | VAF 138/300 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- PDE11A | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 127/277 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PEX16 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 147/324 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- PEX5 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIGC | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 136/467 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- PIK3R6 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 122/265 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PITHD1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 304/641 reads (47%) | SIFT tolerated (0.69); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- PLA2G4D | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 221/452 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PLA2G4E | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 165/379 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLEK2 | c.352A>T p.R118* | Nonsense Mutation (SNP) | VAF 203/415 reads (49%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.3035C>T p.P1012L | Missense Mutation (SNP) | VAF 123/291 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- PLIN3 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 142/281 reads (51%) | SIFT tolerated (0.85); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- POLG2 | c.785G>T p.W262L | Missense Mutation (SNP) | VAF 111/232 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POSTN | c.2126C>T p.P709L | Missense Mutation (SNP) | VAF 108/292 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- PRAMEF14 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 212/431 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PRAMEF17 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 124/233 reads (53%) | SIFT tolerated (0.85); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- PROP1 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 274/536 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PRSS41 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 197/429 reads (46%) | SIFT tolerated (0.9); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PTPRM | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 201/430 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PYDC2 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 81/170 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- RALGAPA1 | c.5251_5265del p.D1751_P1755del | In Frame Del (DEL) | VAF 65/219 reads (30%) | called by mutect2, pindel, varscan2
- RARS1 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 117/258 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASAL1 | c.1182G>A p.R394= | Splice Region (SNP) | VAF 169/332 reads (51%) | called by muse, mutect2, varscan2
- RCC1L | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 103/249 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- RGS7 | c.317C>G p.T106S | Missense Mutation (SNP) | VAF 85/337 reads (25%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- RGSL1 | c.2950G>A p.A984T | Missense Mutation (SNP) | VAF 154/526 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.123); called by muse, varscan2
- RNF128 | c.635C>T p.S212F (on ENST00000255499 / NM_194463.2; = p.S186F on NM_024539.3) | Missense Mutation (SNP) | VAF 186/186 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- RPS6KA2 | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 155/312 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RTN4RL1 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 234/492 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- RUFY4 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 219/438 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, varscan2
- RUFY4 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 194/400 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.054); called by muse, varscan2
- SALL1 | c.3791C>T p.P1264L | Missense Mutation (SNP) | VAF 197/197 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- SCGB1D4 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 121/244 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SCRIB | c.2071G>C p.E691Q | Missense Mutation (SNP) | VAF 270/592 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.121); called by muse, varscan2
- SDR9C7 | c.736T>G p.L246V | Missense Mutation (SNP) | VAF 120/266 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SELP | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 192/520 reads (37%) | SIFT tolerated (0.9); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SEMA3F | c.1801T>C p.F601L | Missense Mutation (SNP) | VAF 170/394 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- SEMA4G | c.2278G>A p.E760K (on ENST00000370250; = p.E765K on NM_017893.3) | Missense Mutation (SNP) | VAF 190/190 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SERPINB12 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 177/354 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC16A14 | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 186/354 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SLC17A7 | c.1410C>G p.Y470* | Nonsense Mutation (SNP) | VAF 130/293 reads (44%) | called by muse, mutect2, varscan2
- SLC45A4 | c.1956C>A p.S652R (on ENST00000517878 / NM_001286646.2; = p.S601R on NM_001080431.2) | Missense Mutation (SNP) | VAF 152/308 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLITRK4 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 198/198 reads (100%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMC1B | c.2630G>C p.R877P | Missense Mutation (SNP) | VAF 184/383 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- SNX6 | c.347G>A p.R116K (on ENST00000652385; = p.R104K on NM_152233.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/253 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPAG6 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 134/134 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SRGAP1 | c.2306C>T p.S769F | Missense Mutation (SNP) | VAF 225/456 reads (49%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ST7 | c.1003C>T p.H335Y (on ENST00000265437 / NM_021908.3; = p.H312Y on NM_018412.4) | Missense Mutation (SNP) | VAF 150/271 reads (55%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNE4 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 300/599 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SYT10 | c.271T>A p.S91T | Missense Mutation (SNP) | VAF 170/338 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAAR9 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 215/452 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TAS2R38 | c.97A>T p.N33Y | Missense Mutation (SNP) | VAF 136/287 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBL3 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 214/421 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- TET3 | c.4991T>G p.L1664R | Missense Mutation (SNP) | VAF 270/538 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEX15 | c.2315A>G p.D772G (on ENST00000256246; = p.D1155G on NM_001350162.2) | Missense Mutation (SNP) | VAF 216/461 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TFR2 | c.1139G>A p.W380* | Nonsense Mutation (SNP) | VAF 129/297 reads (43%) | called by muse, mutect2, varscan2
- TGFBR3 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 162/332 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- TM9SF4 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 116/261 reads (44%) | called by muse, mutect2, varscan2
- TMEM242 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 174/353 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM270 | c.491A>C p.Q164P | Missense Mutation (SNP) | VAF 102/248 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- TMEM63C | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 114/226 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMF1 | c.3253G>A p.D1085N | Missense Mutation (SNP) | VAF 110/244 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2
- TMF1 | c.3251T>A p.I1084K | Missense Mutation (SNP) | VAF 116/254 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TMPRSS11B | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 140/273 reads (51%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TNFRSF11A | c.1573G>A p.V525M | Missense Mutation (SNP) | VAF 94/230 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TOP3A | c.2564G>A p.G855E | Missense Mutation (SNP) | VAF 232/482 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRAJ49 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 141/327 reads (43%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTBK2 | c.3604A>T p.R1202W | Missense Mutation (SNP) | VAF 220/476 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TTC23L | c.905_921del p.L302Cfs*13 | Frame Shift Del (DEL) | VAF 73/189 reads (39%) | called by mutect2, pindel, varscan2
- TTC30B | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 242/494 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TTN | c.80840A>C p.E26947A (on ENST00000591111; = p.E19523A on NM_003319.4) | Missense Mutation (SNP) | VAF 157/341 reads (46%) | PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TTN | c.66994A>C p.K22332Q (on ENST00000591111; = p.K14908Q on NM_003319.4) | Missense Mutation (SNP) | VAF 186/417 reads (45%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TUBB8B | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 134/322 reads (42%) | called by muse, mutect2, varscan2
- TUBGCP5 | c.1333C>T p.L445F | Missense Mutation (SNP) | VAF 238/489 reads (49%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- TXNDC9 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 165/364 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBXN2A | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 207/467 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP11 | c.2396C>T p.P799L (on ENST00000218348; = p.P756L on NM_001371072.1) | Missense Mutation (SNP) | VAF 154/155 reads (99%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP24 | c.4450C>T p.L1484F | Missense Mutation (SNP) | VAF 197/424 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- VAT1L | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 153/328 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS54 | c.2147C>T p.P716L | Missense Mutation (SNP) | VAF 78/174 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- WWTR1 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 54/775 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- XIRP2 | c.3571G>A p.E1191K (on ENST00000628543; = p.E1366K on NM_152381.6) | Missense Mutation (SNP) | VAF 121/234 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- XIRP2 | c.6293C>T p.P2098L (on ENST00000628543; = p.P2273L on NM_152381.6) | Missense Mutation (SNP) | VAF 201/416 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- YME1L1 | c.934C>T p.P312S (on ENST00000326799 / NM_139312.3; = p.P255S on NM_014263.4) | Missense Mutation (SNP) | VAF 107/107 reads (100%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZBTB49 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 137/309 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ZBTB7C | c.1330G>A p.G444S | Missense Mutation (SNP) | VAF 238/491 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZC3H3 | c.2438C>T p.P813L | Missense Mutation (SNP) | VAF 290/657 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZFHX2 | c.4664_4665del p.P1555Rfs*3 | Frame Shift Del (DEL) | VAF 208/476 reads (44%) | called by mutect2, pindel, varscan2
- ZFP57 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 238/545 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ZIC1 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 292/624 reads (47%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZNF100 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 123/254 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF180 | c.1795C>T p.H599Y | Missense Mutation (SNP) | VAF 189/438 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF267 | c.1054T>G p.W352G | Missense Mutation (SNP) | VAF 149/323 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZNF366 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 240/446 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- ZNF408 | c.1373C>T p.T458I | Missense Mutation (SNP) | VAF 248/538 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF445 | c.797A>G p.N266S | Missense Mutation (SNP) | VAF 178/351 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ZNF486 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 162/300 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- ZNF488 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 268/532 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.316); called by muse, mutect2
- ZNF573 | c.1831G>A p.E611K (on ENST00000536220 / NM_001172692.1; = p.E553K on NM_152360.3) | Missense Mutation (SNP) | VAF 194/368 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ZNF607 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 229/466 reads (49%) | called by muse, mutect2, varscan2
- ZNF705A | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 78/360 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.253); called by muse, mutect2
- ZNF737 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 140/298 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- ZNF80 | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 192/456 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF813 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 130/253 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNF835 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 220/425 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZPBP2 | c.384G>C p.K128N (on ENST00000348931 / NM_199321.3; = p.K106N on NM_198844.3) | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZSWIM6 | c.3242C>T p.S1081F | Missense Mutation (SNP) | VAF 188/371 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABAT | c.18C>T p.L6= | Silent (SNP) | VAF 172/349 reads (49%) | catalogued as rs766349160; ClinVar: likely benign; called by muse, mutect2, varscan2
- ABCC11 | c.1497G>A p.R499= | Silent (SNP) | VAF 265/266 reads (100%) | catalogued as rs777449253, COSV62323019; called by muse, mutect2, varscan2
- ABCC9 | c.4626C>T p.S1542= | Silent (SNP) | VAF 129/305 reads (42%) | catalogued as rs771917219; called by muse, mutect2, varscan2
- ABCG2 | c.549C>T p.I183= | Silent (SNP) | VAF 116/247 reads (47%) | called by muse, mutect2, varscan2
- ACRBP | c.1404G>A p.Q468= | Silent (SNP) | VAF 159/322 reads (49%) | called by muse, mutect2, varscan2
- ADAM23 | c.2190C>T p.A730= | Silent (SNP) | VAF 193/398 reads (48%) | called by muse, mutect2, varscan2
- ADAM29 | c.1251G>A p.K417= | Silent (SNP) | VAF 222/454 reads (49%) | catalogued as rs145402389; called by muse, mutect2, varscan2
- ADAM7 | c.1206C>T p.F402= | Silent (SNP) | VAF 135/293 reads (46%) | called by muse, mutect2, varscan2
- ADGRB2 | c.3613C>T p.L1205= | Silent (SNP) | VAF 133/302 reads (44%) | catalogued as COSV57070460; called by muse, mutect2, varscan2
- ADGRB2 | c.3612C>T p.F1204= | Silent (SNP) | VAF 138/308 reads (45%) | catalogued as rs551659755; called by muse, mutect2, varscan2
- ADSL | c.1365G>A p.Q455= | Silent (SNP) | VAF 120/234 reads (51%) | catalogued as rs1011687452; called by muse, mutect2, varscan2
- AK9 | c.1122A>G p.P374= | Silent (SNP) | VAF 124/261 reads (48%) | catalogued as rs529670344; called by muse, mutect2, varscan2
- ANAPC1 | c.4336T>C p.L1446= | Silent (SNP) | VAF 48/151 reads (32%) | called by muse, mutect2, varscan2
- ANKRD24 | c.2835G>A p.K945= | Silent (SNP) | VAF 360/675 reads (53%) | called by muse, mutect2, varscan2
- APLNR | c.936C>T p.F312= | Silent (SNP) | VAF 205/428 reads (48%) | catalogued as rs753058631, COSV57241797; called by mutect2, varscan2
- APMAP | c.1209C>T p.F403= | Silent (SNP) | VAF 170/353 reads (48%) | catalogued as COSV54173685; called by muse, mutect2, varscan2
- ARG1 | c.51G>A p.K17= | Silent (SNP) | VAF 190/374 reads (51%) | called by muse, mutect2, varscan2
- ARHGEF10L | c.1794G>A p.V598= | Silent (SNP) | VAF 197/408 reads (48%) | called by muse, mutect2, varscan2
- ARHGEF15 | c.2280G>A p.Q760= | Silent (SNP) | VAF 142/336 reads (42%) | called by muse, mutect2, varscan2
- ASIC4 | c.1272C>T p.L424= (on ENST00000347842 / NM_182847.3; = p.L443= on NM_018674.6) | Silent (SNP) | VAF 172/355 reads (48%) | catalogued as rs752194666; called by muse, mutect2, varscan2
- ASXL1 | c.3864T>G p.G1288= | Silent (SNP) | VAF 196/421 reads (47%) | catalogued as COSV60106323; called by muse, mutect2, varscan2
- ATF4 | c.732G>A p.R244= | Silent (SNP) | VAF 190/400 reads (48%) | called by muse, mutect2, varscan2
- BRSK2 | c.744G>A p.R248= | Silent (SNP) | VAF 220/446 reads (49%) | called by muse, mutect2, varscan2
- C12orf71 | c.672C>T p.I224= | Silent (SNP) | VAF 234/461 reads (51%) | catalogued as COSV70282920; called by muse, mutect2, varscan2
- CA6 | c.723G>A p.R241= | Silent (SNP) | VAF 148/287 reads (52%) | called by muse, mutect2, varscan2
- CACNA1A | c.1692C>T p.F564= | Silent (SNP) | VAF 129/284 reads (45%) | catalogued as rs377320715; called by muse, mutect2, varscan2
- CACNA1D | c.3939C>T p.I1313= (on ENST00000350061 / NM_001128840.3; = p.I1333= on NM_000720.4) | Silent (SNP) | VAF 106/252 reads (42%) | called by muse, mutect2
- CACNA2D1 | c.2904C>T p.S968= (on ENST00000356253 / NM_001366867.1; = p.S956= on NM_000722.4) | Silent (SNP) | VAF 136/283 reads (48%) | catalogued as COSV62374844; called by muse, mutect2, varscan2
- CAPZA3 | c.387G>A p.V129= | Silent (SNP) | VAF 157/340 reads (46%) | called by muse, mutect2, varscan2
- CARS1 | c.1242C>T p.F414= | Silent (SNP) | VAF 143/314 reads (46%) | called by muse, mutect2, varscan2
- CATSPER4 | c.1068C>T p.L356= | Silent (SNP) | VAF 249/496 reads (50%) | called by muse, mutect2, varscan2
- CCDC163 | c.414C>T p.S138= | Silent (SNP) | VAF 124/296 reads (42%) | catalogued as COSV100517015; called by muse, mutect2, varscan2
- CCDC181 | c.1059G>A p.L353= | Silent (SNP) | VAF 143/232 reads (62%) | catalogued as rs1295448521, COSV63158283; called by muse, mutect2, varscan2
- CCDC182 | c.306G>A p.R102= | Silent (SNP) | VAF 222/504 reads (44%) | catalogued as rs1314587914; called by muse, mutect2, varscan2
- CCNB3 | c.3522C>T p.S1174= | Silent (SNP) | VAF 94/94 reads (100%) | catalogued as COSV52073028; called by muse, mutect2, varscan2
- CCT8L2 | c.414G>A p.T138= | Silent (SNP) | VAF 193/437 reads (44%) | catalogued as rs760129001, COSV63461676, COSV63462106; called by muse, mutect2, varscan2
- CD101 | c.36C>T p.L12= | Silent (SNP) | VAF 156/342 reads (46%) | called by muse, mutect2, varscan2
- CD8A | c.201C>T p.P67= | Silent (SNP) | VAF 276/566 reads (49%) | called by muse, mutect2, varscan2
- CDH10 | c.897G>A p.G299= | Silent (SNP) | VAF 239/439 reads (54%) | catalogued as rs1185825881, COSV52587367; called by muse, mutect2, varscan2
- CDH10 | c.60C>T p.C20= | Silent (SNP) | VAF 198/396 reads (50%) | catalogued as COSV52570087; called by muse, varscan2
- CDH23 | c.2031C>T p.F677= | Silent (SNP) | VAF 174/386 reads (45%) | catalogued as rs759239589, COSV54925526; called by muse, mutect2, varscan2
- CDH23 | c.7632G>A p.L2544= | Silent (SNP) | VAF 139/278 reads (50%) | catalogued as rs775191895, COSV56456099; called by muse, mutect2, varscan2
- CDKL1 | c.408G>A p.T136= | Silent (SNP) | VAF 135/303 reads (45%) | catalogued as COSV53582993; called by muse, mutect2, varscan2
- CDSN | c.919C>T p.L307= | Silent (SNP) | VAF 373/745 reads (50%) | called by muse, mutect2
- CELSR1 | c.1341C>T p.I447= | Silent (SNP) | VAF 257/511 reads (50%) | catalogued as rs756932458, COSV99418115; called by muse, mutect2, varscan2
- CFAP58 | c.987C>T p.I329= | Silent (SNP) | VAF 172/172 reads (100%) | catalogued as COSV100458795; called by muse, mutect2, varscan2
- CHD5 | c.3111G>A p.R1037= | Silent (SNP) | VAF 119/287 reads (41%) | catalogued as COSV52409047; called by muse, mutect2, varscan2
- CHL1 | c.852G>A p.G284= (on ENST00000397491 / NM_001253387.1; = p.G300= on NM_006614.4) | Silent (SNP) | VAF 171/329 reads (52%) | called by muse, mutect2, varscan2
- CHST3 | c.984G>A p.E328= | Silent (SNP) | VAF 229/505 reads (45%) | called by muse, mutect2, varscan2
- CLCA4 | c.480C>T p.L160= | Silent (SNP) | VAF 141/299 reads (47%) | catalogued as COSV55367612; called by muse, mutect2, varscan2
- CLTC | c.1989C>T p.S663= | Silent (SNP) | VAF 133/273 reads (49%) | called by muse, mutect2, varscan2
- CNOT4 | c.603G>A p.K201= | Silent (SNP) | VAF 83/211 reads (39%) | catalogued as COSV59650705; called by muse, mutect2, varscan2
- COL19A1 | c.1704C>T p.G568= | Silent (SNP) | VAF 158/392 reads (40%) | called by muse, mutect2, varscan2
- COL6A3 | c.2958C>T p.I986= | Silent (SNP) | VAF 181/396 reads (46%) | catalogued as rs145203676; called by muse, mutect2, varscan2
- COL6A5 | c.4536G>A p.G1512= | Silent (SNP) | VAF 146/303 reads (48%) | called by muse, mutect2, varscan2
- CRB2 | c.2289C>T p.F763= | Silent (SNP) | VAF 584/585 reads (100%) | catalogued as COSV63505616; called by muse, mutect2, varscan2
- CREB3L3 | c.1053G>A p.G351= | Silent (SNP) | VAF 194/397 reads (49%) | called by muse, mutect2, varscan2
- CTAGE4 | c.2226C>T p.F742= | Silent (SNP) | VAF 59/635 reads (9%) | catalogued as COSV100967778; called by muse, mutect2, varscan2
- CTNND2 | c.225C>T p.I75= | Silent (SNP) | VAF 211/440 reads (48%) | catalogued as COSV58869893; called by muse, mutect2, varscan2
- CUEDC2 | c.863G>A p.*288= | Silent (SNP) | VAF 167/167 reads (100%) | called by muse, mutect2, varscan2
- CXCR1 | c.660C>T p.F220= | Silent (SNP) | VAF 214/428 reads (50%) | called by muse, mutect2, varscan2
- DACH1 | c.975A>T p.A325= | Silent (SNP) | VAF 120/256 reads (47%) | called by muse, mutect2, varscan2
- DCAF4L1 | c.1080G>A p.E360= | Silent (SNP) | VAF 136/315 reads (43%) | catalogued as COSV100295928, COSV60788575; called by muse, mutect2, varscan2
- DGKZ | c.1851G>A p.E617= (on ENST00000454345 / NM_001105540.2; = p.E429= on NM_003646.4) | Silent (SNP) | VAF 197/377 reads (52%) | called by muse, mutect2, varscan2
- DLL1 | c.1929C>T p.L643= | Silent (SNP) | VAF 317/648 reads (49%) | catalogued as rs758149257, COSV100815974, COSV64536598; called by muse, mutect2, varscan2
- DNAH10 | c.6339C>T p.F2113= (on ENST00000409039; = p.F2052= on NM_207437.3) | Silent (SNP) | VAF 286/577 reads (50%) | catalogued as COSV68996529, COSV69004066; called by muse, mutect2, varscan2
- DNAH10 | c.6534G>A p.G2178= (on ENST00000409039; = p.G2117= on NM_207437.3) | Silent (SNP) | VAF 222/488 reads (45%) | catalogued as rs1290578911, COSV101292051; called by muse, mutect2, varscan2
- DNAJC14 | c.45C>T p.H15= | Silent (SNP) | VAF 158/331 reads (48%) | called by muse, mutect2, varscan2
- DOCK3 | c.2880C>T p.F960= | Silent (SNP) | VAF 159/325 reads (49%) | called by muse, mutect2, varscan2
- DYSF | c.6102C>T p.T2034= | Silent (SNP) | VAF 214/483 reads (44%) | called by muse, mutect2, varscan2
- E4F1 | c.1416C>T p.F472= | Silent (SNP) | VAF 271/569 reads (48%) | catalogued as COSV57039466; called by muse, mutect2, varscan2
- EEF1A2 | c.447C>T p.I149= | Silent (SNP) | VAF 331/643 reads (51%) | catalogued as rs772964838, COSV53208572; ClinVar: likely benign; called by muse, mutect2, varscan2
- EHD2 | c.423C>T p.L141= | Silent (SNP) | VAF 94/220 reads (43%) | catalogued as rs1470367232; called by muse, mutect2, varscan2
- EML4 | c.2274G>A p.R758= | Silent (SNP) | VAF 149/295 reads (51%) | called by muse, mutect2, varscan2
- ENC1 | c.165G>A p.R55= | Silent (SNP) | VAF 164/356 reads (46%) | called by muse, mutect2, varscan2
- EVI5L | c.2022C>T p.G674= | Silent (SNP) | VAF 201/486 reads (41%) | called by muse, mutect2, varscan2
- F2 | c.597C>T p.S199= | Silent (SNP) | VAF 183/363 reads (50%) | catalogued as rs576714300, COSV100319624; called by muse, mutect2, varscan2
- FBXL13 | c.609G>A p.V203= | Silent (SNP) | VAF 106/216 reads (49%) | called by muse, mutect2, varscan2
- FBXL7 | c.1024C>T p.L342= | Silent (SNP) | VAF 239/532 reads (45%) | catalogued as rs752807427; called by muse, mutect2, varscan2
- FLG | c.7683G>A p.R2561= | Silent (SNP) | VAF 219/621 reads (35%) | catalogued as rs143745201, COSV64245905, COSV64250535; called by muse, mutect2, varscan2
- FLYWCH2 | c.246G>A p.Q82= | Silent (SNP) | VAF 323/664 reads (49%) | called by muse, mutect2, varscan2
- FMN2 | c.2634C>T p.P878= | Silent (SNP) | VAF 304/916 reads (33%) | catalogued as rs1369118118, COSV100146950; called by muse, mutect2, varscan2
- FOXD2 | c.1317C>T p.F439= | Silent (SNP) | VAF 330/663 reads (50%) | called by muse, mutect2, varscan2
- FOXK2 | c.1755C>T p.V585= | Silent (SNP) | VAF 151/277 reads (55%) | called by muse, mutect2, varscan2
- FPR3 | c.618C>T p.F206= | Silent (SNP) | VAF 235/486 reads (48%) | catalogued as rs755324777, COSV59328545; called by muse, mutect2, varscan2
- FRMPD4 | c.249G>A p.R83= | Silent (SNP) | VAF 182/183 reads (99%) | catalogued as rs761069076, COSV66222017; called by muse, mutect2, varscan2
- FSTL5 | c.1473C>T p.P491= | Silent (SNP) | VAF 132/274 reads (48%) | catalogued as rs1247464471; called by muse, mutect2, varscan2
- FUT3 | c.696G>A p.G232= | Silent (SNP) | VAF 310/603 reads (51%) | catalogued as rs765224654; called by muse, mutect2, varscan2
- GALNT8 | c.888G>A p.Q296= | Silent (SNP) | VAF 151/306 reads (49%) | called by muse, mutect2, varscan2
- GATA3 | c.567C>T p.P189= | Silent (SNP) | VAF 348/349 reads (100%) | catalogued as rs768165292; called by muse, mutect2, varscan2
- GGA1 | c.876C>T p.N292= | Silent (SNP) | VAF 127/281 reads (45%) | called by muse, mutect2, varscan2
- GGA1 | c.877C>T p.L293= | Silent (SNP) | VAF 127/284 reads (45%) | called by muse, mutect2, varscan2
- GOLGA1 | c.1731G>A p.Q577= | Silent (SNP) | VAF 412/412 reads (100%) | called by muse, mutect2, varscan2
- GRM8 | c.2184G>A p.Q728= | Silent (SNP) | VAF 179/378 reads (47%) | called by muse, mutect2, varscan2
- HDAC9 | c.1656G>A p.V552= | Silent (SNP) | VAF 165/362 reads (46%) | catalogued as COSV101286768; called by muse, mutect2, varscan2
- HIPK1 | c.3231C>T p.L1077= (on ENST00000369558 / NM_001369806.1; = p.L683= on NM_181358.2) | Silent (SNP) | VAF 226/491 reads (46%) | catalogued as rs760001128, COSV61248897; called by muse, mutect2, varscan2
- HIRA | c.2859C>T p.Y953= | Silent (SNP) | VAF 110/205 reads (54%) | catalogued as rs1556010857, COSV54272570; called by muse, mutect2, varscan2
- HOXC13 | c.510G>A p.K170= | Silent (SNP) | VAF 288/606 reads (48%) | catalogued as rs760431752; called by muse, mutect2, varscan2
- HOXD3 | c.762G>A p.K254= | Silent (SNP) | VAF 226/508 reads (44%) | called by muse, mutect2, varscan2
- HPS4 | c.1167C>T p.F389= | Silent (SNP) | VAF 201/408 reads (49%) | called by muse, mutect2, varscan2
- HPS6 | c.2070C>T p.L690= | Silent (SNP) | VAF 296/297 reads (100%) | catalogued as rs1210018155; called by muse, mutect2, varscan2
- HYDIN | c.14079C>T p.P4693= | Silent (SNP) | VAF 146/417 reads (35%) | called by muse, mutect2, varscan2
- IGHM | c.1305G>A p.G435= | Silent (SNP) | VAF 158/306 reads (52%) | catalogued as rs1178554497; called by muse, mutect2, varscan2
- IGLV8-61 | c.249G>A p.G83= | Silent (SNP) | VAF 247/457 reads (54%) | catalogued as rs1412480210; called by muse, mutect2, varscan2
- IKZF2 | c.270G>A p.V90= | Silent (SNP) | VAF 259/507 reads (51%) | catalogued as rs1480206985; called by muse, mutect2, varscan2
- ILDR1 | c.1572G>A p.R524= (on ENST00000344209 / NM_001199799.2; = p.R480= on NM_175924.4) | Silent (SNP) | VAF 134/285 reads (47%) | catalogued as rs1375830170, COSV56549871; called by muse, mutect2, varscan2
- INPPL1 | c.1587T>C p.S529= | Silent (SNP) | VAF 170/391 reads (43%) | called by muse, mutect2, varscan2
- INTS1 | c.4968C>T p.F1656= | Silent (SNP) | VAF 166/358 reads (46%) | catalogued as COSV67177423; called by muse, mutect2, varscan2
- JAG2 | c.3552C>T p.G1184= | Silent (SNP) | VAF 299/692 reads (43%) | called by muse, mutect2, varscan2
- JPH1 | c.1422C>T p.H474= | Silent (SNP) | VAF 209/421 reads (50%) | catalogued as rs777783295; called by muse, mutect2, varscan2
- KCNA6 | c.1302G>A p.G434= | Silent (SNP) | VAF 238/482 reads (49%) | called by muse, mutect2, varscan2
- KIAA1549 | c.4758C>T p.F1586= | Silent (SNP) | VAF 123/250 reads (49%) | called by muse, mutect2, varscan2
- KIF19 | c.918C>T p.L306= | Silent (SNP) | VAF 141/263 reads (54%) | called by muse, mutect2, varscan2
- KITLG | c.768G>A p.E256= | Silent (SNP) | VAF 107/220 reads (49%) | catalogued as rs573914379, COSV57204009; called by muse, mutect2, varscan2
- KLHL14 | c.1413G>A p.G471= | Silent (SNP) | VAF 149/318 reads (47%) | catalogued as COSV63831936; called by muse, mutect2, varscan2
- KLHL14 | c.792C>T p.L264= | Silent (SNP) | VAF 306/563 reads (54%) | catalogued as rs758386114; called by muse, mutect2, varscan2
- KLHL40 | c.1629C>T p.F543= | Silent (SNP) | VAF 164/339 reads (48%) | catalogued as COSV55134672; called by muse, mutect2, varscan2
- KRTAP10-12 | c.135C>T p.A45= | Silent (SNP) | VAF 343/709 reads (48%) | catalogued as rs1555950771; called by muse, mutect2, varscan2
- LAMB1 | c.2349C>T p.S783= | Silent (SNP) | VAF 192/400 reads (48%) | catalogued as rs775144042, COSV55962240, COSV55969152; ClinVar: likely benign; called by muse, mutect2, varscan2
- LIPK | c.720C>T p.F240= | Silent (SNP) | VAF 219/220 reads (100%) | catalogued as COSV101344960; called by muse, mutect2, varscan2
- LRP1B | c.4806C>T p.V1602= | Silent (SNP) | VAF 155/348 reads (45%) | catalogued as COSV101254960, COSV67194478; called by muse, mutect2, varscan2
- LRRC43 | c.21C>T p.S7= | Silent (SNP) | VAF 234/507 reads (46%) | catalogued as rs767979161; called by muse, mutect2, varscan2
- LRRC43 | c.1701G>A p.R567= | Silent (SNP) | VAF 255/555 reads (46%) | catalogued as COSV60291592; called by muse, mutect2, varscan2
- LRRC4C | c.1038G>A p.Q346= | Silent (SNP) | VAF 212/441 reads (48%) | catalogued as COSV53432332, COSV53437506; called by muse, mutect2, varscan2
- MAGEA10 | c.705C>T p.F235= | Silent (SNP) | VAF 242/242 reads (100%) | called by muse, mutect2, varscan2
- MAP1A | c.4818C>T p.A1606= | Silent (SNP) | VAF 108/265 reads (41%) | called by muse, mutect2, varscan2
- MAP3K4 | c.3036C>T p.F1012= | Silent (SNP) | VAF 178/363 reads (49%) | called by muse, mutect2, varscan2
- MARK4 | c.2016C>T p.A672= | Silent (SNP) | VAF 270/550 reads (49%) | called by muse, mutect2, varscan2
- MAS1 | c.402C>T p.V134= | Silent (SNP) | VAF 232/458 reads (51%) | catalogued as rs140242572; called by muse, mutect2, varscan2
- MBD5 | c.4425C>T p.I1475= | Silent (SNP) | VAF 162/319 reads (51%) | catalogued as COSV68695929; called by muse, mutect2, varscan2
- MDN1 | c.4395C>T p.F1465= | Silent (SNP) | VAF 145/334 reads (43%) | catalogued as COSV65518858; called by muse, mutect2, varscan2
- MED26 | c.1689G>A p.V563= | Silent (SNP) | VAF 188/462 reads (41%) | called by muse, mutect2, varscan2
- MEX3D | c.1050C>T p.P350= | Silent (SNP) | VAF 306/656 reads (47%) | catalogued as rs777460785, COSV66312479; called by muse, mutect2, varscan2
- MGAM2 | c.45C>T p.F15= | Silent (SNP) | VAF 203/427 reads (48%) | called by muse, mutect2, varscan2
- MGAM2 | c.2733G>A p.L911= | Silent (SNP) | VAF 181/393 reads (46%) | catalogued as rs1428658015; called by muse, mutect2, varscan2
- MICU1 | c.1152C>T p.Y384= (on ENST00000361114 / NM_001195518.2; = p.Y390= on NM_006077.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 121/269 reads (45%) | catalogued as rs764422809; called by muse, mutect2, varscan2
- MORC1 | c.354G>A p.T118= | Silent (SNP) | VAF 84/198 reads (42%) | catalogued as rs555321094, COSV51713642; called by muse, mutect2, varscan2
- MSS51 | c.288G>A p.Q96= | Silent (SNP) | VAF 199/408 reads (49%) | called by muse, mutect2, varscan2
- MTARC1 | c.324G>A p.Q108= | Silent (SNP) | VAF 165/459 reads (36%) | catalogued as rs147237295; called by muse, mutect2, varscan2
- MTCL1 | c.906C>T p.V302= | Silent (SNP) | VAF 335/705 reads (48%) | called by muse, mutect2, varscan2
- MUC16 | c.23487G>A p.L7829= | Silent (SNP) | VAF 194/400 reads (49%) | called by muse, mutect2, varscan2
- MUC16 | c.1714C>T p.L572= | Silent (SNP) | VAF 185/376 reads (49%) | catalogued as COSV101199881; called by muse, mutect2, varscan2
- MUC22 | c.3654C>T p.V1218= | Silent (SNP) | VAF 321/738 reads (43%) | called by muse, mutect2, varscan2
- MXRA5 | c.6624G>A p.V2208= | Silent (SNP) | VAF 243/243 reads (100%) | called by muse, mutect2, varscan2
- MYBPH | c.807C>T p.P269= | Silent (SNP) | VAF 144/479 reads (30%) | called by muse, mutect2, varscan2
- MYH1 | c.4263G>A p.T1421= | Silent (SNP) | VAF 125/271 reads (46%) | catalogued as rs370946637; called by muse, mutect2, varscan2
- MYH13 | c.2724G>A p.R908= | Silent (SNP) | VAF 132/316 reads (42%) | catalogued as rs1197533052; called by muse, mutect2, varscan2
- MYH4 | c.2718G>A p.E906= | Silent (SNP) | VAF 130/236 reads (55%) | called by muse, mutect2, varscan2
- MYH4 | c.1527C>T p.I509= | Silent (SNP) | VAF 190/395 reads (48%) | catalogued as rs1462404392, COSV55111358; called by muse, mutect2, varscan2
- MYO1G | c.294C>T p.I98= | Silent (SNP) | VAF 136/291 reads (47%) | catalogued as rs762257344; called by muse, mutect2, varscan2
- MYO5B | c.315C>T p.I105= | Silent (SNP) | VAF 108/226 reads (48%) | catalogued as rs748097712, COSV53215610, COSV53227808; called by muse, mutect2, varscan2
- NAALADL1 | c.321C>T p.S107= | Silent (SNP) | VAF 184/417 reads (44%) | called by muse, mutect2, varscan2
- NBEAL2 | c.2718C>T p.P906= | Silent (SNP) | VAF 195/444 reads (44%) | called by muse, mutect2, varscan2
- NCOA6 | c.5856G>A p.E1952= | Silent (SNP) | VAF 105/211 reads (50%) | catalogued as rs762836072; called by muse, mutect2, varscan2
- NEB | c.19644G>A p.G6548= | Silent (SNP) | VAF 234/488 reads (48%) | called by muse, mutect2
- NEU4 | c.174G>A p.R58= (on ENST00000391969 / NM_001167602.3; = p.R70= on NM_080741.4) | Silent (SNP) | VAF 254/510 reads (50%) | called by muse, mutect2, varscan2
- NLRP5 | c.2686C>T p.L896= | Silent (SNP) | VAF 163/351 reads (46%) | catalogued as rs766306003; called by muse, mutect2, varscan2
- NMT1 | c.687C>T p.I229= | Silent (SNP) | VAF 132/276 reads (48%) | called by muse, mutect2, varscan2
- NOC4L | c.885C>T p.T295= | Silent (SNP) | VAF 146/328 reads (45%) | called by muse, varscan2
- NOVA1 | c.795C>T p.S265= | Silent (SNP) | VAF 159/321 reads (50%) | catalogued as COSV57487758; called by muse, mutect2, varscan2
- NPAS3 | c.2436C>T p.T812= (on ENST00000356141 / NM_001164749.2; = p.T780= on NM_022123.3) | Silent (SNP) | VAF 272/556 reads (49%) | called by muse, mutect2, varscan2
- NPAT | c.1281C>T p.A427= | Silent (SNP) | VAF 154/356 reads (43%) | called by muse, mutect2, varscan2
- NRCAM | c.498C>T p.P166= (on ENST00000379028 / NM_001371124.1; = p.P160= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 157/294 reads (53%) | called by muse, mutect2, varscan2
- NRP2 | c.1956G>A p.E652= | Silent (SNP) | VAF 156/362 reads (43%) | called by muse, mutect2, varscan2
- NRXN3 | c.889C>T p.L297= | Silent (SNP) | VAF 224/473 reads (47%) | called by muse, mutect2, varscan2
- NUP153 | c.2271C>T p.A757= | Silent (SNP) | VAF 165/364 reads (45%) | catalogued as COSV50449674; called by muse, mutect2, varscan2
- OR10A7 | c.267G>A p.R89= | Silent (SNP) | VAF 219/483 reads (45%) | catalogued as rs371021969; called by muse, mutect2, varscan2
- OR1M1 | c.81C>T p.L27= | Silent (SNP) | VAF 172/328 reads (52%) | catalogued as COSV101447571; called by muse, mutect2, varscan2
- OR2W3 | c.138C>T p.I46= | Silent (SNP) | VAF 247/804 reads (31%) | catalogued as COSV64458418; called by muse, mutect2, varscan2
- OR4A8 | c.42C>T p.G14= | Silent (SNP) | VAF 128/246 reads (52%) | catalogued as rs775990977; called by muse, varscan2
- OR4A8 | c.180C>T p.F60= | Silent (SNP) | VAF 156/340 reads (46%) | called by muse, varscan2
- OR4C12 | c.351C>T p.A117= | Silent (SNP) | VAF 175/343 reads (51%) | called by muse, mutect2, varscan2
- OR51G1 | c.765C>T p.I255= | Silent (SNP) | VAF 198/387 reads (51%) | catalogued as COSV58968324, COSV58969126; called by muse, mutect2, varscan2
- OR5A2 | c.811A>C p.R271= | Silent (SNP) | VAF 173/362 reads (48%) | called by muse, mutect2, varscan2
- OR7A5 | c.135C>T p.I45= | Silent (SNP) | VAF 169/371 reads (46%) | called by muse, mutect2, varscan2
- OSBPL7 | c.2094C>T p.L698= | Silent (SNP) | VAF 220/515 reads (43%) | called by muse, mutect2, varscan2
- PAPPA2 | c.3045G>A p.G1015= | Silent (SNP) | VAF 131/406 reads (32%) | catalogued as COSV62808569; called by muse, mutect2, varscan2
- PCCA | c.48G>A p.R16= | Silent (SNP) | VAF 203/446 reads (46%) | called by muse, mutect2, varscan2
- PCDHB5 | c.2100C>T p.F700= | Silent (SNP) | VAF 406/812 reads (50%) | catalogued as rs782504378; called by muse, mutect2
- PCLO | c.4023G>A p.K1341= | Silent (SNP) | VAF 95/225 reads (42%) | catalogued as COSV61621488, COSV61634106; called by muse, mutect2, varscan2
- PCP2 | c.396G>A p.P132= | Silent (SNP) | VAF 163/363 reads (45%) | catalogued as rs376970140; called by muse, mutect2, varscan2
- PEBP4 | c.420C>T p.S140= | Silent (SNP) | VAF 112/280 reads (40%) | catalogued as rs754251581; called by muse, mutect2, varscan2
- PIEZO1 | c.334C>T p.L112= | Silent (SNP) | VAF 109/228 reads (48%) | called by muse, mutect2, varscan2
- PKD1L3 | c.168A>C p.G56= | Silent (SNP) | VAF 209/416 reads (50%) | called by muse, mutect2, varscan2
- PLA2G2D | c.69G>A p.L23= | Silent (SNP) | VAF 166/343 reads (48%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.603G>A p.R201= | Silent (SNP) | VAF 199/429 reads (46%) | called by muse, mutect2, varscan2
- PLIN4 | c.1659G>A p.T553= (on ENST00000301286; = p.T568= on NM_001367868.2) | Silent (SNP) | VAF 229/513 reads (45%) | catalogued as rs767265114; called by muse, varscan2
- POLR3G | c.33T>C p.A11= | Silent (SNP) | VAF 132/279 reads (47%) | called by muse, mutect2, varscan2
128 further variants in this file (0 protein-altering or splice-affecting, 92 silent, 36 other) are not listed here.
